Gene-level copy-number profile of tumor specimen TCGA-XF-A8HB-01A from TCGA case TCGA-XF-A8HB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 50.8 years (18,544 days).
Specimen TCGA-XF-A8HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6f2900d5-0c4e-42cc-b01b-d6a335a17102.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A8HB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b71a14b-e836-4321-8d62-e2e4939d4044

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,239; copy number 2: 46,474; copy number 3: 8,556; copy number 4: 501; copy number 5: 33; copy number 6: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A8HB-01A-11D-A363-01): tumor purity 0.96, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,959,049–42,996,814, 1 gene, copy number 6 (within-gene range 2–6): SLC2A1-AS1.
- chr1:42,991,438–43,023,637, 2 genes, copy number 6: RNU6-880P, U6.
- chr3:161,104,696–161,503,942, 9 genes, copy number 6 (within-gene range 3–6): NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1.
- chr6:69,866,556–71,458,874, 33 genes, copy number 5 (within-gene range 4–5): COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626.

Autosomal genes at a single copy (total copy number 1): 4,236. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
